Somatic mutation profile of tumor specimen TCGA-2H-A9GJ-01A (aliquot TCGA-2H-A9GJ-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.0 years (21,180 days).
Specimen TCGA-2H-A9GJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e34d9c55-8ccd-45fd-8700-0b862a1fdaf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GJ-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GJ-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/983374b9-8a45-414e-8862-d67d330b2910

The open-access MAF lists 109 somatic variants for this specimen: 81 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 24, Nonsense Mutation 5, Frame Shift Del 3, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2B | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs562863484, COSV61658252; called by muse, mutect2, varscan2
- AKT1 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1038322721; called by muse, mutect2, varscan2
- BICDL2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as rs1375074228; called by muse, mutect2, varscan2
- CAMSAP2 | c.2294G>C p.R765T (on ENST00000236925 / NM_001297707.2; = p.R754T on NM_203459.3) | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV52671526; called by muse, mutect2, varscan2
- CCDC110 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs751679746; called by muse, mutect2, varscan2
- CCDC7 | c.2860G>T p.E954* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV56543331, COSV56545707; called by muse, mutect2, varscan2
- DAAM1 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166170856, COSV62834780; called by muse, mutect2, varscan2
- DBX1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV57055206; called by muse, mutect2, varscan2
- EPHA6 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.611); catalogued as COSV67584799, COSV67594646; called by muse, mutect2, varscan2
- EVI5L | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs745770179, CM142390, COSV54488609; called by muse, mutect2, varscan2
- FASTKD5 | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs144604664; called by muse, mutect2, varscan2
- FLG | c.8383G>A p.G2795R | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs779385755, COSV64241727; called by muse, mutect2, varscan2
- FLNC | c.7484G>C p.R2495P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs757219498; called by muse, mutect2, varscan2
- GPATCH2 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1354710788; called by muse, mutect2, varscan2
- HACD1 | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs551814483; called by muse, mutect2, varscan2
- IGKV3D-20 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs189772344; called by muse, varscan2
- LY75-CD302 | c.5131G>A p.E1711K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.938); catalogued as rs746579440, COSV52035058; called by muse, mutect2, varscan2
- METTL4 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs775093191; called by muse, mutect2, varscan2
- MTREX | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.327); catalogued as rs747521885, COSV57925211; called by muse, mutect2, varscan2
- NECTIN3 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1190549551, COSV100162118; called by muse, mutect2, varscan2
- NELL2 | c.352A>T p.S118C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61573239; called by muse, varscan2
- OBSCN | c.7477C>T p.R2493W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs375061154; called by muse, mutect2, varscan2
- OPLAH | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782310069, COSV70678368; called by muse, mutect2, varscan2
- PRTG | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1445356691, COSV101221458, COSV66837501; called by muse, mutect2
- RBL2 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1394382925; called by muse, mutect2, varscan2
- RNF17 | c.4810G>A p.D1604N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs371675646; called by muse, mutect2, varscan2
- ROBO2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59929242, COSV59946557; called by muse, mutect2, varscan2
- SLC22A5 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as rs1166753949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A2 | c.1510C>T p.L504F (on ENST00000494857 / NM_001370338.1; = p.L543F on NM_003046.6) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV50270674; called by muse, mutect2, varscan2
- SMARCA4 | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as rs1378511462, COSV60796065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFA | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781896307; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPST2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447875903, COSV58678649; called by muse, mutect2, varscan2
- TRPV6 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1012823605; called by muse, mutect2, varscan2
- WIPF2 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 44/149 reads (30%) | catalogued as rs1290037543, COSV60274660; called by muse, mutect2, varscan2
- WNK2 | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs781420468; called by muse, mutect2, varscan2
- WWC1 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1255464657; called by muse, mutect2, varscan2
- ZAN | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs221826; called by muse, varscan2
- ZNF536 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV62825295; called by muse, mutect2
- ZNF710 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs1228715585; called by muse, mutect2, varscan2
- ADAMTS7 | c.1131C>A p.D377E | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AKAP9 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- AP4B1 | c.629T>A p.L210Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- BNIP3 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CAPN12 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.329); called by muse, mutect2
- CHRNG | c.795_798del p.A267Rfs*42 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by pindel, varscan2
- CLCA2 | c.1592A>G p.Q531R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CLRN3 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); called by muse, varscan2
- CT55 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CTNNA3 | c.1724C>T p.T575I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DCSTAMP | c.737A>T p.Y246F | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- DDI1 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- FBXO25 | c.385T>A p.L129M (on ENST00000382824 / NM_183421.2; = p.L62M on NM_012173.3) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FOXG1 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GBP6 | c.1598A>C p.K533T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPRIN1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- HCRTR2 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 30/219 reads (14%) | called by muse, mutect2, varscan2
- INO80 | c.3523A>C p.S1175R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IRS1 | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- KCNJ3 | c.802_808dup p.I270Tfs*15 | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | called by mutect2, varscan2
- KIDINS220 | c.2310_2312del p.V771del | In Frame Del (DEL) | VAF 10/71 reads (14%) | called by pindel, varscan2
- LCE1F | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LIMK2 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K19 | c.2140A>G p.T714A | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED23 | c.1481C>G p.A494G | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- NELFCD | c.680A>C p.E227A (on ENST00000602795; = p.E209A on NM_198976.4) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NELL2 | c.382C>A p.H128N | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, varscan2
- NR2F6 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- OR52N1 | c.742T>A p.C248S | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RAB3IP | c.397G>C p.E133Q (on ENST00000550536 / NM_175623.4; = p.E117Q on NM_022456.5) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SECISBP2L | c.2072C>T p.T691I (on ENST00000559471 / NM_001193489.2; = p.T646I on NM_014701.4) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SIGLEC11 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLAMF7 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TLN2 | c.5255C>A p.S1752Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TRHDE | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- VSIG4 | c.868A>C p.I290L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WDR59 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- YTHDF2 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ZBTB7B | c.1174del p.H392Tfs*107 (on ENST00000292176; = p.H426Tfs*107 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel
- ZMYM4 | c.89_128del p.G30Afs*3 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel
- ZNF789 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADORA2A | c.396G>A p.S132= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs201432461; called by muse, mutect2, varscan2
- AFF3 | c.1839G>A p.A613= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1267167428; called by muse, mutect2
- APBA2 | c.633C>A p.R211= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- APP | c.522C>T p.C174= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs199905579, COSV61000831; called by muse, mutect2, varscan2
- CYCS | c.177C>A p.I59= | Silent (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- DNAAF6 | c.417C>T p.C139= | Silent (SNP) | VAF 37/46 reads (80%) | catalogued as COSV100314524; called by muse, mutect2, varscan2
- MCM8 | c.1467A>C p.V489= | Silent (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- MOAP1 | c.276C>T p.I92= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- MRPS30 | c.753G>T p.V251= | Silent (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
- MUC16 | c.32169T>C p.A10723= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV101202437; called by muse, mutect2, varscan2
- NCAPD2 | c.2436C>T p.A812= | Silent (SNP) | VAF 52/66 reads (79%) | called by muse, mutect2, varscan2
- NFYB | c.219T>G p.P73= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- ORC3 | c.1749T>C p.A583= | Silent (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- PRAM1 | c.474G>A p.P158= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs372388181, COSV55314067; called by muse, mutect2, varscan2
- PRPF6 | c.1488C>A p.A496= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- RARS1 | c.210T>A p.T70= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- SDK1 | c.2187C>T p.T729= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs763373679, COSV67370567; called by muse, mutect2, varscan2
- SHROOM2 | c.687G>T p.T229= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2334C>T p.P778= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs779542594; called by muse, mutect2, varscan2
- SLC12A8 | c.366C>T p.I122= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs757205892, COSV58872715; called by muse, mutect2, varscan2
- SPTA1 | c.3792A>G p.K1264= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- TMCC1 | c.183G>A p.R61= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs759899503; called by muse, mutect2, varscan2
- ZAN | c.2346C>T p.I782= | Silent (SNP) | VAF 44/184 reads (24%) | catalogued as rs370655016; called by muse, varscan2
- ZNF285 | c.1095A>G p.V365= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs781287235; called by muse, mutect2, varscan2
- ANKRD50 | c.-2T>A | 5'UTR (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- CASP2 | c.967+114_967+116del | Intron (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- CUTA | chr6:33418124 C>T | 5'Flank (SNP) | VAF 8/136 reads (6%) | catalogued as rs368867314; called by muse, mutect2
- SUPT20HL2 | c.-546G>A | 5'UTR (SNP) | VAF 52/57 reads (91%) | catalogued as rs771550951; called by muse, mutect2, varscan2
